Somatic mutation profile of tumor specimen 0E0CT9 from CCDI case PBCVBB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E0CT9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e48b5c3d-3b2b-4967-ad57-8229f9798787.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0CV2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54955d06-c589-449a-8ab8-0ef44fdc2dc6

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Nonsense Mutation 2, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 206/728 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs121913238, COSV55502066, COSV55502677; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FYB1 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 257/885 reads (29%) | catalogued as COSV60947473; called by muse, mutect2, varscan2
- KBTBD11 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.357); catalogued as rs1301132729; called by muse, mutect2
- KLK7 | c.641C>A p.T214N | Missense Mutation (SNP) | VAF 86/285 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- NELL1 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 24/910 reads (3%) | called by muse, mutect2
- RPUSD3 | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 136/468 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TSEN2 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 36/858 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EMILIN1 | c.1344G>A p.Q448= | Silent (SNP) | VAF 10/289 reads (3%) | called by muse, mutect2
- KRAS | c.180T>A p.G60= | Silent (SNP) | VAF 208/726 reads (29%) | catalogued as rs397517037, COSV55499291, COSV55523567, COSV99782811; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDX60 | c.4270-45T>A | Intron (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- OBSL1 | c.-82C>G | 5'UTR (SNP) | VAF 2/14 reads (14%) | called by muse, mutect2
